Surgical pathology report (de-identified scan), TCGA case TCGA-29-2428, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-2428-01A (Primary Tumor).

[page 1 of 3]
TCGA-29-2428

Surg Path

CLINICAL HISTORY:

Abdominal/pelvic swelling. History- high grade endometrium carcinoma (from Pap), left adnexal mass (retrograde endometrial carcinoma ?).

GROSS EXAMINATION:

A. "Left tube and ovary (AF1)". Received fresh is a 10.5 x 8.9 x 8.5 cm multicystic, serous fluid filled and hemorrhagic ovary filled with tumor that is nodular and exudative. The serosa is intact. A 3.0 x 3.5 x 2.0 cm ovarian remnant is identified adjacent to it. The 6.0 x 0.7 x 0.5 cm fallopian tube in which the distal end is obscured by a 4.0 x 3.0 x 2.5 cm tan-white, homogenous tumor (AF1 Frozen section; remnant in A1, additional blocks A).

BLOCK SUMMARY:

A1- AF1 remnant.
A2- tube and tumor (longitudinal section).
A3- tube (cross sections, surgical margin inked black).
A4- residual ovary and mass.
A5- hemorrhagic cyst and mass.
A6-A7- mass with fibrinous exudate.

B. "Uterus, left tube and ovary (gross consult)". Received fresh and placed in formalin is a 48.9 gram, 7.3 x 6.7 x 2.5 cm uterus, a 2.5 x 0.7 x 0.6 cm segment of fallopian tube (fimbria not identified) and a 2.5 x 1.8 x 0.8 cm tan-white ovary. The ovary, fallopian tube, and uterus are all grossly unremarkable. Nabothian cysts are identified in the endocervix.

BLOCK SUMMARY:

B1- fallopian tube and ovary.
B2- anterior endomyometrium.
B3- anterior cervix.
B4- posterior endomyometrium.
B5- posterior cervix.

C. "Left periaortic node (CF1)". Received fresh and placed in formalin is a 3.0 x 1.5 x 1.0 cm lymph node of which part consists for frozen section CF1. The remaining fragment are submitted in blocks C2-C4.

D. "Perirectal mass". Received fresh and placed in formalin. A 3.3 x 3.0 x 2.3 cm aggregate of fibrofatty tissue and peritoneum, which on cut section demonstrates a 2.7 x 2.2 x 1.5 cm tan-white, nodular mass, which measures 0.2 cm from the blue-inked outer surface. Representative in D1-4.

E. "Left pelvic mass". Received fresh and placed in formalin. Two tan-white tissue fragments, which measure in aggregate 2.5 x 2.5 x 1.1 cm. The outer surface is inked blue. The larger fragment (2.5 x 1.6 x 1.0 cm) demonstrates a tan-white homogenous cut surface that extends to the blue inked outer surface. Representative in E1-2.

F. "Left external iliac node". Received fresh and placed in formalin. A 4.3 x 2.5 x 1.2 cm aggregate of fibrofatty tissue, which is dissected for lymph node candidates. One lymph node candidate is identified and submitted entirely in F1.

G. "Left obturator nodes". Received fresh and placed in formalin. A 5.7 x 2.5 x 2.4 cm aggregate of fibrofatty, which is dissected for lymph node candidates. Two lymph node candidates are identified. The largest lymph node candidate measures 4.3 x 2.0 x 0.7 cm. The smaller lymph node candidate represents a mat of two apparent lymph nodes.

[page 2 of 3]
BLOCK SUMMARY:

G1-3- one lymph node candidate
G4-5- one lymph node candidate

H. "Right external node". Received fresh and placed in formalin. A 3.5 x 3.0 x 1.0 cm aggregate of fibrofatty tissue which dissected for lymph node candidates. The largest lymph node candidate measures 1.8 x 1.4 x 0.5 cm.

BLOCK SUMMARY:

H1- four lymph node candidates
H2- one lymph node candidate
H3- two lymph node candidates

I. "Right obturator nodes". Received fresh and placed in formalin. A 5.5 x 2.5 x 1.0 cm aggregate of fibrofatty tissue, which is dissected for lymph node candidates. The largest lymph node candidate measures 5.0 x 1.4 x 0.5 cm.

BLOCK SUMMARY:

I1-2- one lymph node candidate
I3- three lymph node candidates (one inked blue and bisected)

J. "Omentum". Received fresh and placed in formalin. A 22.0 x 18.0 x 4.0 cm aggregate of omentum no masses or lesions are identified.

INTRA OPERATIVE CONSULTATION:

A. "Left tube and ovary":AF1- papillary serous adenocarcinoma
B. "Uterus, left tube, ovary":BF1- grossly benign
C. "Left periaortic node":CF1 metastatic serous adenocarcinoma

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: HYSTERECTOMY, OOPHORECTOMY & LYMPH NODES

PATHOLOGIC STAGE pt3C pN1 .PMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "LEFT OVARY":

TYPE: SEROUS ADENOCARCINOMA
FIGO GRADE: 3
TUMOR SIZE: 10.5 X 8.9 X 8.5 CM.
WEIGHT: N.A.
Serosa: INVOLVED
ADDITIONAL FINDINGS: NONE

SPECIMENS WITH METASTATIC/IMPLANTED TUMOR

A. LEFT FALLOPIAN TUBE, 4.0 CM NODULE AT TERMINUS

B. UTERUS: 50 GRAMS

ENDOMETRIUM:

TUMOR SITE: LOWER POLYP IN THE LOWER UTERINE SEGMENT INTO THE CERVIX.
HISTOLOGIC TYPE: SEROUS ADENOCARCINOMA.
FIGO GRADE: 3

[page 3 of 3]
TUMOR SIZE: 4 MM.

MAXIMUM DEPTH OF MYOMETRIAL INVASION: 0 CM, IN A 1.2 CM THICK WALL.

LYMPHATIC/VASCULAR INVASION: NEGATIVE

ADJACENT NON-NEOPLASTIC ENDOMETRIUM: ATROPHIC

REMAINING MYOMETRIUM: NEGATIVE

CERVIX: NEGATIVE

SEROSA: NO PATHOLOGIC DIAGNOSIS.

C. LEFT PERIAORTIC LYMPH NODE: ONE OF ONE NODE POSITIVE (3 CM).

D. PERIRECTAL MASS: METASTATIC TUMOR, 2.7 CM.

E. LEFT PELVIC MASS: 0.5 CM TUMOR NODULE.

F. LEFT EXTERNAL ILIAC LYMPH NODE: ONE OF ONE NODE, POSITIVE (0/1).

THE FOLLOWING SPECIMENS ARE FREE OF TUMOR:

G. RIGHT OBTURATOR LYMPH NODE: NO TUMOR IN 10 LYMPH NODES (0/10).

H. RIGHT EXTERNAL ILIAC NODE: NO TUMOR IN 7 LYMPH NODES (0/7).

I. RIGHT OBTURATOR: NO TUMOR IN 8 LYMPH NODES (0/8).

J. OMENTUM.

NOTE: The origin of the tumor, a serous adenocarcinoma, is most likely of ovarian origin, although there is some degree of uncertainty. Key features are (1) large size of the ovarian tumor and (2) WT-1 reactivity which is usually positive in ovarian serous primaries, but usually negative in endometrial serous primaries. While there was a past history of endometrial tumor detected by pap smear, it is possible this is from cells shed by the ovarian tumor that have passed through the reproductive canal. The tumor also occupies half of the endometrial polyp, including its interior, which is not typical for a metastasis, but certainly can be expected if present for some period of time. The polyp arises in the lower uterine segment and has prolapsed into the cervix.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

ADDENDUM 1:

The tumor is reactive for P53 and WT1. The former was omitted accidentally from the report.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file d45b2665-9cfb-4c48-b4f8-9b747165b2fc (TCGA-29-2428.45A6C74C-045B-4FDD-A93D-9E1A8D36E4CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).